Gene-level copy-number profile of tumor specimen ALCH-B2SM-TTP1-A from ALCHEMIST case ALCH-B2SM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.0 years (24,842 days).
Specimen ALCH-B2SM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 693f0c81-7455-4803-a81c-01c280ad624b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,795 have no estimate.
https://portal.gdc.cancer.gov/files/c23c7919-7da2-482c-81e7-7c8dc484d6b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 335; copy number 1: 2,538; copy number 2: 25,006; copy number 3: 12,481; copy number 4: 9,438; copy number 5: 2,129; copy number 6: 3,875; copy number 7: 1,072; copy number 8: 567; copy number 9: 166; copy number 10: 150; copy number 11: 487; copy number 12: 74; copy number 13: 123; copy number 14: 205; copy number 16: 46; copy number 17: 35; copy number 20: 79; copy number 22: 9; copy number 32: 11; copy number 35: 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:42,915,989–42,963,880, 6 genes (within-gene range 0–5): PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT.
- chr6:142,058,330–142,088,799, 2 genes (within-gene range 0–6): NMBR, AL589674.1.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr22:50,274,979–50,445,090, 5 genes (within-gene range 0–2): PLXNB2, DENND6B, CR559946.1, CR559946.2, PPP6R2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,030 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 27 genes, copy number 6–8: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:31,727,117–50,023,954, 524 genes, copy number 6–13 (within-gene range 2–13) (broad region; genes not listed).
- chr1:119,140,391–120,467,739, 39 genes, copy number 6–8 (within-gene range 2–8): WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2.
- chr1:121,314,947–157,310,655, 644 genes, copy number 5–7 (broad region; genes not listed).
- chr2:38,814–94,604,573, 1,599 genes, copy number 5–9 (broad region; genes not listed).
- chr2:104,580,821–107,748,270, 58 genes, copy number 7–10: AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886.
- chr2:119,759,922–120,351,803, 15 genes, copy number 5: PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB.
- chr4:103,924,540–104,037,543, 2 genes, copy number 5: RNU6-635P, LINC02503.
- chr5:58,198–45,895,970, 679 genes, copy number 7–16 (broad region; genes not listed).
- chr6:42,963,865–43,369,647, 25 genes, copy number 5 (within-gene range 0–5): PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1.
- chr6:55,680,642–57,913,911, 26 genes, copy number 5: AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.1, AL021368.2.
- chr6:122,531,123–141,636,503, 273 genes, copy number 6 (broad region; genes not listed).
- chr6:142,088,233–170,738,536, 468 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr7:22,812,628–23,014,130, 6 genes, copy number 9: TOMM7, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A.
- chr7:84,528,122–84,584,322, 2 genes, copy number 7: RPL7P30, AC003984.1.
- chr7:141,351,977–159,233,377, 456 genes, copy number 6 (broad region; genes not listed).
- chr10:47,689,707–48,119,455, 12 genes, copy number 5: SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr10:48,292,699–48,982,956, 11 genes, copy number 6 (within-gene range 2–6): RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2.
- chr10:53,458,197–58,370,751, 27 genes, copy number 5: RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1.
- chr11:68,980,021–71,252,577, 56 genes, copy number 5–7: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr12:12,310–27,325,959, 682 genes, copy number 6–7 (broad region; genes not listed).
- chr12:27,466,810–27,502,185, 2 genes, copy number 5: SMCO2, RARS1P1.
- chr12:50,103,982–50,167,533, 4 genes, copy number 6: GPD1, COX14, AC074032.1, CERS5.
- chr12:89,319,364–102,958,410, 260 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:77,895,481–78,617,328, 3 genes, copy number 7 (within-gene range 3–7): EDNRB, OBI1-AS1, AL139002.1.
- chr13:77,979,817–85,544,570, 52 genes, copy number 7–35 (within-gene range 3–35): LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, LINC01038, LINC00382, AL158064.1, LINC01080, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5, AL445255.1, GYG1P2, AL512782.1, RNU6-67P, SLITRK1, AL355481.1, VENTXP2, UBE2D3P4, MTND4P1, MTND5P3, LINC00333, LINC00375, LINC00351.
- chr13:92,484,606–92,510,094, 2 genes, copy number 10 (within-gene range 3–10): GPC5-IT1, MIR548AS.
- chr13:93,032,972–93,227,317, 2 genes, copy number 6–8 (within-gene range 2–8): LINC00363, AL354811.1.
- chr13:107,868,823–113,364,148, 95 genes, copy number 14–22 (broad region; genes not listed).
- chr14:18,333,726–18,667,370, 18 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3.
- chr17:34,169,372–37,406,836, 140 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:47,967,810–52,899,588, 183 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:23,399,233–39,435,949, 441 genes, copy number 5–20 (broad region; genes not listed).
- chr19:45,863,989–45,974,044, 5 genes, copy number 7: FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2.
- chr19:47,019,837–58,605,223, 853 genes, copy number 6–9 (broad region; genes not listed).
- chr20:87,250–13,996,443, 277 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:16,982,831–26,251,546, 224 genes, copy number 5 (broad region; genes not listed).
- chr20:31,341,371–32,439,319, 50 genes, copy number 7–32: HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1.
- chr22:20,859,007–22,043,934, 77 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr22:22,179,228–40,410,289, 703 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
